Surgical pathology report (de-identified scan), TCGA case TCGA-61-2612, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2612-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OMENTUM, OMENTECTOMY -

HIGH GRADE PAPILLARY SEROUS ADENOCARCINOMA

PART 2: APPENDIX, APPENDECTOMY -

APPENDIX WITH METASTATIC HIGH GRADE PAPILLARY SEROUS ADENOCARCINOMA INFILTRATING SEROSA, MUSCULARIS AND SUBMUCOSA.

PART 3: ADDITIONAL PORTION OF APPENDIX, EXCISION -

METASTATIC HIGH GRADE PAPILLARY SEROUS ADENOCARCINOMA.

PART 4: SIGMOID COLON, EXCISION -

A. METASTATIC HIGH GRADE PAPILLARY SEROUS ADENOCARCINOMA INVOLVING SEROSA AND MUSCULARIS.

B. MARGINS OF EXCISION SHOWING LYMPHOVASCULAR INVASION BY HIGH GRADE PAPILLARY SEROUS ADENOCARCINOMA.

PART 5: LEFT OVARY, LEFT SALPINGO-OOPHORECTOMY -

A. HIGH GRADE PAPILLARY SEROUS ADENOCARCINOMA INVOLVING FIBROADIPOSE TISSUE.

B. NO NORMAL OVARIAN STROMA OR FALLOPIAN TUBE IDENTIFIED.

PART 6: RIGHT OVARY, RIGHT SALPINGO-OOPHORECTOMY -

A. HIGH GRADE PAPILLARY SEROUS ADENOCARCINOMA OF RIGHT OVARY WITH INVOLVEMENT OF OVARIAN SURFACE.

B. RIGHT FALLOPIAN TUBE WITH HIGH GRADE PAPILLARY SEROUS ADENOCARCINOMA IN PERITUBAL TISSUE.

PART 7: UTERUS WITHOUT ADNEXA (26 GRAMS), TOTAL ABDOMINAL HYSTERECTOMY -

A. CHRONIC CERVICITIS WITH NABOTHIAN CYSTS.

B. INACTIVE ENDOMETRIUM.

C. LEIOMYOMA, MICROSCOPIC.

D. HIGH GRADE PAPILLARY SEROUS ADENOCARCINOMA INVOLVING SEROSA AND EXTENDING TO MYOMETRIUM

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

A. Laterality: 3

1. Right 2. Left 3. Bilateral

B. Procedure: 4

1. Cystectomy 4. TAH with salpingo-oophorectomy
2. Salpingo-oophorectomy 5. Other
3. Bilateral salpingo-oophorectomy

C. Tumor size (maximum dimension): 5.5 cm

D. Histologic type: 2

1. Papillary serous tumor, BL*	12. Undifferentiated Carcinoma
2. Papillary serous carcinoma	13. Small cell carcinoma
3. Mucinous tumor, BL	14. Mature teratoma
4. Mucinous carcinoma	15. Immature teratoma
5. Endometrioid tumor, BL	16. Dysgerminoma
6. Endometrioid carcinoma	17. Embryonal carcinoma
7. Clear cell tumor, BL	18. Yolk sac tumor
8. Clear cell carcinoma	19. Granulosa cell tumor, Juvenile
9. Brenner tumor, BL	20. Granulosa cell tumor, adult
10. Malignant Brenner tumor	21. Malignant lymphoma
11. Malignant mixed Müllerian tumor	22. Others

E. Histologic Grade: 3

1. Well 2. Moderate 3. Poorly differentiated

F. Vascular Invasion: 1

1. Yes 2. No

G. Tumor capsule: 1

1. Intact 2. Ruptured

H. Surface implants: 1

1. Invasive 2. Non-invasive 3. Not present

I. Surface implants:

1. Uterus: 1 1. Yes 2. No

2. Fallopian tubes: 1 1. Yes 2. No

3. Omentum: 1 1. Yes 2. No

4. Peritoneal metastasis beyond the pelvis: 3

1. Microscopic 2. Less than 2 cms 3. More than 2 cms

J. Associated other lesion: N/A

1. Endometriosis.

2. Abnormalities of surface epithelium or surface epithelial inclusion.

3. Others.

K. Malignant cells in ascites or peritoneal washing: 1 1. Yes 2. No

L. Nodes involved: N/A

L1. Number of positive lymph nodes: #

L2. Total number of lymph nodes examined: #

L3. Pelvic: Right: # positive/total # Left: # positive/total #

L4. Obturator: Right: # positive/total # Left: # positive/total #

L5. Common iliac: Right: # positive/total # Left: # positive/total #

L6. External iliac: Right: # positive/total # Left: # positive/total #

L7. Para-aortic: Right: # positive/total # Left: # positive/total #

L8. Inguinal: Right: # positive/total # Left: # positive/total #

M. Extracapsular lymph node spread N/A 1. Yes 2. No

N. TNM Stage: T IIIB N X M X

O. FIGO Stage: IIIB

Source: NCI Genomic Data Commons file be58d07c-300a-454d-b00e-52ad9ff16b3e (TCGA-61-2612.48D32D40-9EEF-43D2-BEB6-75FCC071C52B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).